Somatic mutation profile of tumor specimen C3L-04242-54 (aliquot CPT0230840002) from CPTAC case C3L-04242, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 55.7 years (20,327 days).
Specimen C3L-04242-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f431d75-c1a8-44d3-9626-3a9d51fb9a41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04242-51 (Buccal Cell Normal), aliquot CPT0230940001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4c515ed-cba4-4f39-a53d-a44501b6245d

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.696_697insGG p.N233Gfs*52 (on ENST00000344691 / NM_001001890.3; = p.N260Gfs*52 on NM_001754.5) | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, varscan2
